Gene-level copy-number profile of tumor specimen ALCH-B6U7-TTP1-A from ALCHEMIST case ALCH-B6U7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.2 years (20,173 days).
Specimen ALCH-B6U7-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f3401818-5a50-4f73-abba-50dd6b1dbf87.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B6U7-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/c5017aa7-303a-4068-9b97-fc77584e8c7a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 702; copy number 2: 53,341; copy number 3: 4,354; copy number 4: 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:113,577,382–113,607,908, 6 genes: FAM138B, AL078621.2, MIR1302-3, WASH2P, DDX11L2, AL078621.1.
- chr16:46,469,341–46,569,097, 2 genes: ANKRD26P1, RNU6-845P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 697. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
